Somatic mutation profile of tumor specimen C3N-01417-04 (aliquot CPT0105780009) from CPTAC case C3N-01417, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.2 years (23,444 days).
Specimen C3N-01417-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5c4292e-02a3-4d54-8ab2-355ae9e402f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01417-71 (Blood Derived Normal), aliquot CPT0108220004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57057f83-6069-4de5-af59-d8fc7c5dcef6

The open-access MAF lists 80 somatic variants for this specimen: 55 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Splice Site 3, Intron 3, 5'UTR 2, Frame Shift Del 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 206/572 reads (36%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 144/237 reads (61%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV101001021; called by muse, mutect2, varscan2
- APP | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 47/662 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61004727; called by muse, mutect2
- BMPER | c.952A>G p.N318D | Missense Mutation (SNP) | VAF 463/899 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.625); catalogued as COSV51814389, COSV51817398; called by muse, mutect2, varscan2
- BRD1 | c.2543G>T p.R848L (on ENST00000216267 / NM_001349940.1; = p.R979L on NM_001304808.3) | Missense Mutation (SNP) | VAF 293/764 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs372097126; called by muse, mutect2, varscan2
- CDH23 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 96/161 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376301184; called by muse, mutect2, varscan2
- CPSF1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52779048; called by muse, mutect2
- DNAH14 | c.4853A>G p.N1618S (on ENST00000445597; = p.N2023S on NM_001367479.1) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs756473599; called by muse, mutect2, varscan2
- FAM160A1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1195592473; called by muse, mutect2, varscan2
- H3C2 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 68/603 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV52517865, COSV52518608, COSV52520327; called by muse, mutect2, varscan2
- LRRC63 | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 100/137 reads (73%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1448260316; called by muse, mutect2, varscan2
- MCUR1 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1463516634; called by muse, mutect2, varscan2
- NLRP12 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs766308091, COSV60757158; ClinVar: uncertain significance; called by muse, mutect2
- OBSCN | c.9413C>T p.S3138F | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs779219952; called by muse, mutect2, varscan2
- OR2T11 | c.103del p.A35Pfs*2 | Frame Shift Del (DEL) | VAF 65/320 reads (20%) | catalogued as rs759832412; called by mutect2, pindel, varscan2
- RHAG | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 61/613 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs751577470, COSV57705094, COSV57705413; called by muse, mutect2, varscan2
- SPTA1 | c.4339-1G>A p.X1447_splice | Splice Site (SNP) | VAF 52/728 reads (7%) | catalogued as COSV63753399, COSV63757635; called by muse, mutect2
- SYNE1 | c.364G>T p.V122F (on ENST00000367255 / NM_182961.4; = p.V129F on NM_033071.3) | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55072355; called by muse, mutect2, varscan2
- TGIF2LX | c.436T>A p.S146T | Missense Mutation (SNP) | VAF 316/437 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV99383168; called by muse, mutect2, varscan2
- TRIM64B | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1295776421; called by mutect2, varscan2
- WDR48 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs867151772; called by muse, mutect2, varscan2
- ZC3H10 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs760083256, COSV99230517; called by muse, mutect2, varscan2
- ZNF341 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs376738185; called by muse, mutect2, varscan2
- ABCG8 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AP5B1 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.371); called by muse, mutect2
- AQP8 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 159/591 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ARHGEF28 | c.3482C>T p.A1161V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ATP6V0D2 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CALN1 | c.404A>G p.E135G (on ENST00000329008 / NM_001017440.3; = p.E177G on NM_031468.4) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CCDC105 | c.1430C>A p.A477E | Missense Mutation (SNP) | VAF 172/235 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CEP170B | c.3865G>T p.A1289S (on ENST00000453495; = p.A1218S on NM_015005.3) | Missense Mutation (SNP) | VAF 167/219 reads (76%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- CLCA4 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2
- DEPDC1 | c.1363C>A p.L455M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.087); called by muse, mutect2
- EFHB | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ENPP1 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 107/366 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAAP20 | c.471-2_476del p.X157_splice | Splice Site (DEL) | VAF 146/342 reads (43%) | called by mutect2, pindel, varscan2
- KLHL29 | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- NEB | c.8279T>A p.L2760H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NUP210 | c.4800C>G p.I1600M | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5B3 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 134/378 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PLCB3 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PRKCA | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RANBP9 | c.1041_1050del p.K348Hfs*3 | Frame Shift Del (DEL) | VAF 50/229 reads (22%) | called by mutect2, pindel, varscan2
- RBM47 | c.1408A>G p.I470V (on ENST00000295971 / NM_001098634.2; = p.I401V on NM_019027.4) | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBX20 | c.1113C>A p.S371R | Missense Mutation (SNP) | VAF 380/724 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TINF2 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 442/574 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMEM253 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 226/310 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIM64B | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, varscan2
- USP33 | c.1509A>T p.Q503H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR11 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 141/266 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- XIRP1 | c.2238A>T p.Q746H | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYND11 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ZNF696 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNRF2 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 181/350 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ANKRD6 | c.546G>A p.A182= | Silent (SNP) | VAF 18/272 reads (7%) | catalogued as rs375469086, COSV60233074; called by muse, mutect2
- CCDC107 | c.813G>T p.T271= | Silent (SNP) | VAF 41/67 reads (61%) | called by muse, mutect2, varscan2
- CENPF | c.6621G>A p.T2207= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs1271362005, COSV65277064; called by muse, mutect2
- CORO1B | c.84C>T p.D28= | Silent (SNP) | VAF 184/435 reads (42%) | called by muse, mutect2, varscan2
- CPS1 | c.795G>A p.P265= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs1174421173, COSV51802928, COSV51817111; called by muse, mutect2, varscan2
- DPP6 | c.1014C>A p.T338= (on ENST00000377770 / NM_001364500.2; = p.T276= on NM_001936.5) | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV59622606; called by muse, varscan2
- JAKMIP1 | c.1347G>A p.V449= | Silent (SNP) | VAF 70/275 reads (25%) | called by muse, mutect2, varscan2
- MTMR12 | c.522T>A p.A174= | Silent (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- MYRFL | c.988C>T p.L330= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- NLRP3 | c.195G>A p.A65= | Silent (SNP) | VAF 179/442 reads (40%) | catalogued as rs201205620; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTSR2 | c.534C>T p.H178= | Silent (SNP) | VAF 26/218 reads (12%) | catalogued as rs994512625; called by muse, mutect2, varscan2
- OR1L8 | c.63G>T p.R21= | Silent (SNP) | VAF 68/90 reads (76%) | called by muse, mutect2, varscan2
- PARP12 | c.1191G>A p.V397= | Silent (SNP) | VAF 66/165 reads (40%) | called by muse, mutect2, varscan2
- PCNT | c.4773C>T p.I1591= | Silent (SNP) | VAF 76/407 reads (19%) | catalogued as rs375111791; called by muse, mutect2, varscan2
- SCYL1 | c.1059G>A p.V353= | Silent (SNP) | VAF 96/306 reads (31%) | catalogued as rs951641117; called by muse, mutect2, varscan2
- SLC38A10 | c.1491C>T p.H497= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs747750986, COSV99917964; called by muse, mutect2
- ST6GAL2 | c.237G>A p.A79= | Silent (SNP) | VAF 78/113 reads (69%) | catalogued as COSV64525920; called by muse, mutect2, varscan2
- TTLL9 | c.894C>T p.I298= | Silent (SNP) | VAF 38/328 reads (12%) | catalogued as rs767220808; called by muse, mutect2, varscan2
- ZNF771 | c.705G>T p.V235= | Silent (SNP) | VAF 40/363 reads (11%) | called by muse, mutect2, varscan2
- ESR1 | c.452+866G>C | Intron (SNP) | VAF 7/151 reads (5%) | called by muse, mutect2
- GRIK1 | c.1098+12254T>C | Intron (SNP) | VAF 29/190 reads (15%) | called by muse, mutect2, varscan2
- HBS1L | c.430+2849G>A | Intron (SNP) | VAF 41/89 reads (46%) | catalogued as rs554261166; called by muse, mutect2, varscan2
- PPIL1 | c.-5T>G | 5'UTR (SNP) | VAF 135/368 reads (37%) | called by muse, mutect2, varscan2
- VSIG8 | c.-10G>T | 5'UTR (SNP) | VAF 10/182 reads (5%) | catalogued as rs1471883989; called by muse, mutect2
- Y_RNA | chr7:75516146 C>T | 5'Flank (SNP) | VAF 65/618 reads (11%) | called by muse, mutect2, varscan2
